HCMI case HCM-WCMC-1292-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a4f7fe06-4bef-4e32-afce-f3fa80588aa4

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Papillary transitional cell carcinoma: ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.8; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Overlapping lesion of bladder; Classification of tumor: primary; Age at diagnosis: 60.3 years (22,029 days); AJCC clinical stage: Stage IV; Tumor grade: G3; Prior malignancy: yes; Prior treatment: Yes.
   Pathology details: Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Neoadjuvant; Days to treatment start: 414 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 841 days (2.3 years); Days to treatment end: 953 days (2.6 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Enfortumab Vedotin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,240 days (3.4 years); Days to treatment end: 1,457 days (4.0 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,240 days (3.4 years); Days to treatment end: 1,695 days (4.6 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Sacituzumab Govitecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,534 days (4.2 years); Days to treatment end: 1,765 days (4.8 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,805 days (4.9 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 1,457.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 187 cm; BMI: 27.

Exposures
- Tobacco smoking status: Current Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-WCMC-1292-C67-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-1292-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
